CPTAC case C3L-02841 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64a43fad-5906-4c02-875e-37590ba66935

Demographics
Sex at birth: male; Race: white; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 60.3 years (22,011 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G4; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,062 days (2.9 years); Progression or recurrence: no; Days to last follow up: 1,062 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 11 cm (a second GDC size field records 5 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 5; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 335 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 685 days (1.9 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 13 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,062 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 124.28 kg; Height: 180.34 cm; BMI: 38.21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02841-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 270 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02841-21: Section location: Tumor occupied 95% of upper to lower poles; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-02841-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 130 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02841-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
